Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RJ-01A (Primary Tumor).

[page 1 of 4]
Sex: F

Specimen Description

Surgical Pathology Report

Patient Name:

Accession #:

Med. Rec #:

Submitting P:

100-0-3

carcinoma, squamous cell, nos 8070/3

Site: cervix, nos C53.9

hw
9/8/11

*****Clinical History*****

Cervical cancer, Stage IB2.

*****Final Pathologic Diagnosis*****

- A. Left parametrium, excision:
- Benign fibroadipose tissue and vessels.
- B. Right parametrium, excision:
- Benign fibroadipose tissue and vessels.
- C. Uterus, upper vagina, bilateral fallopian tubes and ovaries, radical hysterectomy, bilateral salpingo-oophorectomy:
- Cervix with poorly differentiated squamous cell carcinoma, see synoptic report.
- Parametrial soft tissue with endosalpingiosis and no evidence of carcinoma.
- Two parametrial lymph nodes negative for carcinoma (0/2).
- Vaginal mucosa with severe squamous dysplasia (VAIN-3), present at margin of resection.
- Proliferative endometrium.
- Myometrium with leiomyomata.
- Bilateral fallopian tubes with no pathological data.
- Bilateral ovaries with hemorrhagic corpora lutea.
- D. Right pelvic lymph nodes, excision:
- Seven lymph nodes negative for carcinoma (0/7).
- E. Left pelvic lymph nodes, excision:
- Eleven lymph nodes negative for carcinoma (0/11).
- F. Left common iliac lymph nodes, excision:
- Benign fibroadipose tissue.
- G. Right common iliac lymph nodes, excision:
- Two lymph nodes negative for carcinoma (0/2).

SYNOPTIC REPORT FOR CERVICAL CANCER:

Specimen type: radical hysterectomy and bilateral salpingo-oophorectomy,

[page 2 of 4]
bilateral pelvic lymphadenectomy.

Tumor location: anterior ectocervix with extension into endocervix.

Tumor size: 4.7 x 2.5 x 0.4cm (posterior), 2.5cm x 1.3cm x 0.4cm (anterior).

Histologic type: squamous cell carcinoma.

Tumor grade: high grade (poorly differentiated, see note).

Lymphatic/vascular invasion: present.

Tumor extent:

Depth of stromal invasion (in cm/mm): 0.4cm (22%).

Breadth of stromal invasion ("horizontal spread"): 4.7cm.

Involvement of vagina: not by invasive carcinoma but it is involved by VAIN-3.

Involvement of uterus: no.

Involvement of parametria: no.

Involvement of pelvic wall: no.

Involvement of other adjacent structures: (bladder, rectum, ovaries, etc) no.

Margins:

Vaginal margins: negative for invasive carcinoma but involved by VAIN-3.

Anterior and posterior cervical soft tissue margins: negative.

Parametrial margins: negative.

Distance from tumor to all margins: 1.5cm from stromal margin, 2.1cm from posterior vaginal cuff margin.

Lymph nodes:

Total number examined by location: 18 pelvic lymph nodes, 2 iliac lymph nodes, 2 parametrial lymph nodes.

Number positive: 0.

Number negative: 22.

Extranodal extension: n/a

Size of largest metastatic deposit: n/a

Special studies:

pTNM: pT1b2N0MX.

Note: Large areas of the tumor do show clear cytoplasmic features. Also seen are more discrete but definite areas with more typical non-keratinizing squamous cell carcinoma. Immunohistochemistry will be reported as an addendum.

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

Electronically Signed By

*****SPECIMEN(S) RECEIVED:*****

A: GYN, NOS, REG

[page 3 of 4]
B: GYN, NOS, REG
C: Uterus, tubes, ovaries, REG
D: Lymph node, GYN, REG
E: Lymph node, GYN, REG
F: Lymph node, GYN, REG
G: Lymph node, GYN, REG

*****GROSS DESCRIPTION:*****

The specimens are received in seven properly labeled containers with the patient's name and accession number.

A. The specimen is designated "left perimetrium" and consists of two portions of tan to yellow soft tissue that are 1.8 x 1.2 x 0.4 cm and 1.5 x 1.0 x 0.7 cm. Each portion of tissue is bisected. TE 1

B. The specimen is designated "right perimetrium" and consists of a 3.0 x 1.8 x 1.0 cm aggregate of multiple portions of tan-yellow soft tissue. One of the portions of tissue contains a staple line. The specimen is serially sectioned. RS 2

Summary of Cassettes: B1-2, entire specimen, only the staple line remains in the container

C. The specimen is designated "radical hysterectomy (uterus, cervix, upper vagina)" and consists of a 231.4 gram uterus and cervix with attached bilateral adnexal structures that is 9.6 cm from fundus to posterior vaginal cuff margin, 4.8 cm from cornu to cornu and 4.3 cm from anterior to posterior. The serosa is tan-pink and smooth. Right and left parametrium is present which is shaved and entirely submitted. The serosa, cervical resection margins and parametrium are inked as follows: anterior = blue, posterior = black. Portions of anterior and posterior, grossly unremarkable vaginal cuff is present which ranges in length from 0.8 to 2.9 cm. The anterior vaginal cuff is tan-white, wrinkled and displays no discrete lesions. The posterior vaginal cuff is tan-white to brown and slightly thickened. No discrete lesions are identified on the mucosal surface. The anterior ectocervical mucosa displays a 2.5 cm (width) x 1.3 cm (length) tan-brown, endophytic, ulcerated mass that is 2.5 cm from the anterior vaginal cuff margin. Cut sections through the mass are tan-white, smooth, have a maximum depth of 0.3 cm and are 1.5 cm from the blue-inked stromal margin. The posterior ectocervix contains a red-brown to gray-green, rubbery, exophytic mass that is 4.7 cm (width) x 2.5 cm (length). The mass is 2.1 cm from the posterior vaginal cuff margin. Cut sections through the mass are tan-pink to white, have a maximum depth of 1.9 cm and are 1.1 cm from the black-inked stromal margin. The anterior mass is grossly confined to the ectocervix while the posterior mass extends to involve the endocervical mucosa. The triangular endometrial cavity is lined by a tan-pink to red, soft endometrium that is 0.2 cm in average thickness. No discrete endometrial lesions are identified. The myometrium is tan-pink, moderately trabeculated and contains three tan-white, well-circumscribed, rubbery, whorled nodules that range from 0.4 cm in greatest dimension to 0.7 x 0.6 x 0.5 cm. The nodules are located in the intramural aspect of the anterior and posterior myometrium. Upon sectioning, no areas of hemorrhage or necrosis are identified. The right tubo-ovarian complex is 10.5 grams. The previously interrupted fimbriated fallopian tube is 3.5 cm in length x 0.6 cm in diameter. The serosa is purple and wrinkled. Cut sections reveal a lumen. The tan-yellow to purple, focally cystic right ovary is 3.2 x 2.2 x 2.0 cm. The cut surfaces are tan-white, lobulated and contain two smooth-walled, blood-filled cysts

[page 4 of 4]
that are 0.9 x 0.7 x 0.7 cm and 1.7 x 1.4 x 1.2 cm. Both blood-filled cysts are consistent with hemorrhagic corpora lutea. The left tubo-ovarian complex is 9.4 grams. The previously interrupted fimbriated fallopian tube is 3.1 cm in length x 0.6 cm in diameter. The serosa is tan-pink and smooth. Cut sections reveal a lumen. The tan-yellow to purple, focally cystic left ovary is 2.9 x 2.1 x 1.9 cm. The cut surfaces are tan-white, lobulated, and contain multiple smooth-walled, subcortical cysts which range from 0.2 cm in greatest dimension to 1.4 x 1.0 x 0.9 cm. Some of the cysts contain clotted blood and are consistent with hemorrhagic corpora lutea. One cyst contains a thin, straw-colored fluid. RS 32

Summary of Cassettes: C1-4, right parametrium, shave; C5-7, left parametrium, shave; C8, anterior vaginal cuff margin, shaved and trisected; C9, posterior vaginal cuff margin, shaved and serially sectioned; C10-12, full-thickness sections of anterior cervix and mass; C13-20, each two cassettes contains one bisected full-thickness section of posterior cervix and mass (inked orange at point of bisection, endocervical half submitted first and stromal half submitted second); C21, anterior lower uterine segment/upper endocervix (uterine end inked green); C22, posterior lower uterine segment/upper endocervix (uterine end inked green); C23, full-thickness sections of anterior uterine wall; C24, full-thickness sections of posterior uterine wall; C25, largest myometrial nodule, bisected and entirely submitted; C26, second largest myometrial nodule with remainder in cassette C24; C27, cross sections of right fallopian tube; C28-29, sections of right ovary; C30, cross sections of left fallopian tube; C31-32, sections of left ovary

D. The specimen is designated "R pelvic lymph nodes" and consists of a 5.5 x 3.5 x 1.5 cm aggregate of adipose tissue that upon dissection contains seven possible lymph nodes that range from 0.2 cm in greatest dimension to 4.0 x 1.1 x 0.8 cm. RS 5

Summary of Cassettes: D1-2, largest lymph node, serially sectioned; D3-4, each cassette contains one bisected lymph node; D5, four lymph nodes; only adipose tissue remains in the container

E. The specimen is designated "left pelvic lymph nodes" and consists of a 6.0 x 4.5 x 2.0 cm aggregate of adipose tissue that upon dissection contains 11 possible lymph nodes that range from 0.4 cm in greatest dimension to 3.4 x 1.3 x 0.7 cm. RS 5

Summary of Cassettes: E1-2, largest lymph node, serially sectioned; E3, three lymph nodes; E4, four lymph nodes; E5, three lymph nodes; only adipose tissue remains in the container

F. The specimen is designated "left common iliac lymph nodes" and consists of a 1.5 x 1.0 x 0.5 cm aggregate of adipose tissue that upon dissection contains no grossly identifiable lymph nodes. TE 1

G. The specimen is designated "R common iliac lymph nodes" and consists of a 2.0 x 2.0 x 1.0 cm aggregate of adipose tissue that upon dissection contains two possible lymph nodes that are 0.4 cm in greatest dimension and 2.7 x 1.3 x 0.5 cm. RS 1

Summary of Cassettes: G1, two lymph nodes; only adipose tissue remains in the container

Lab Use Only: Job ID

Source: NCI Genomic Data Commons file c63959c3-e6c7-43b4-b958-f0671489e9ad (TCGA-EK-A2RJ.6761746F-0149-4AE4-840F-D99B8FCEF6F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).